Somatic mutation profile of tumor specimen TCGA-X2-A95T-01A (aliquot TCGA-X2-A95T-01A-11D-A37C-09) from TCGA case TCGA-X2-A95T, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 49.5 years (18,079 days).
Specimen TCGA-X2-A95T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c7ca1cc-9a04-466b-ba01-998ceafa11e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X2-A95T-10A (Blood Derived Normal), aliquot TCGA-X2-A95T-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd07fec-fd73-4a26-8901-b3e01eb41810

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 14, Silent 9, In Frame Del 2, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.15679C>T p.P5227S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99948112; called by muse, mutect2, varscan2
- ASAP2 | c.1733T>C p.L578P | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99856384; called by muse, mutect2, varscan2
- CENPU | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs766591368, COSV99860012; called by muse, mutect2, varscan2
- CFAP206 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV51534442, COSV99739740; called by muse, mutect2, varscan2
- FRMD1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767371388, COSV51963145; called by muse, mutect2, varscan2
- FUZ | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776318983, COSV100571188; called by muse, mutect2, varscan2
- HYLS1 | c.896_898del p.S299del | In Frame Del (DEL) | VAF 19/35 reads (54%) | catalogued as rs771348153; called by pindel, varscan2
- KCNMB3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100046594, COSV58571743; called by muse, mutect2, varscan2
- LETM1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100245495; called by muse, mutect2, varscan2
- MMP24 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99863928; called by muse, mutect2, varscan2
- PLXNB2 | c.4300A>G p.K1434E | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834130; called by muse, mutect2, varscan2
- PRR27 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60641149; called by muse, mutect2, varscan2
- RARB | c.645C>A p.D215E (on ENST00000383772 / NM_001290216.2; = p.D208E on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100412568, COSV100412699; called by muse, mutect2, varscan2
- SETD1A | c.4582-2_4582-1del p.X1528_splice | Splice Site (DEL) | VAF 32/65 reads (49%) | catalogued as rs755127868; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SLC7A9 | c.965T>G p.F322C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195348; called by muse, mutect2, varscan2
- STK36 | c.3706C>T p.R1236W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as rs776619847, COSV99831582; called by muse, mutect2, varscan2
- TADA3 | c.870_871del p.A292* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs1342617130; called by mutect2, pindel, varscan2
- TENM3 | c.2432A>C p.Y811S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101305210; called by muse, mutect2, varscan2
- TEX10 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.73); PolyPhen benign (0.049); catalogued as COSV100887847; called by muse, mutect2, varscan2
- TP53 | c.339_341del p.F113del | In Frame Del (DEL) | VAF 29/32 reads (91%) | catalogued as rs764486868; called by pindel, varscan2
- TSC22D2 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV100721238; called by muse, mutect2, varscan2
- AFM | c.23del p.G8Vfs*9 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.2328_2358del p.S778Qfs*26 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- ATMIN | c.1632_1633del p.H544Qfs*7 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- ATRX | c.1274_1275del p.K425Rfs*8 | Frame Shift Del (DEL) | VAF 15/22 reads (68%) | called by mutect2, pindel, varscan2
- IRF3 | c.957_958del p.F320* | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by pindel, varscan2
- MICALL1 | c.1652_1653del p.P551Rfs*19 | Frame Shift Del (DEL) | VAF 48/69 reads (70%) | called by mutect2, pindel, varscan2
- MTFR1 | c.925_928del p.R309Cfs*8 | Frame Shift Del (DEL) | VAF 22/25 reads (88%) | called by mutect2, pindel, varscan2
- NSUN5 | c.995_998del p.H332Pfs*51 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- PRKAR2B | c.644_645del p.Y215* | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- RSL1D1 | c.325_326del p.K109Dfs*6 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.690_691del p.F233* | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- TRIM52 | c.69_72del p.C23Wfs*21 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- UGGT1 | c.1748_1749del p.K583Sfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- MTCL1 | c.2760C>T p.S920= (on ENST00000306329 / NM_001378206.1; = p.S560= on NM_015210.4) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1369898927, COSV100094895; called by muse, mutect2
- OR1S1 | c.474A>T p.T158= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV100515430; called by muse, mutect2, varscan2
- PPP2R2A | c.525T>G p.A175= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100277242; called by muse, mutect2, varscan2
- RAD54L | c.1767C>T p.V589= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100586432; called by muse, mutect2, varscan2
- RBP3 | c.1848C>T p.I616= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs782370605; called by muse, mutect2, varscan2
- RSF1 | c.222G>A p.L74= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57846953; called by muse, mutect2, varscan2
- SYT6 | c.1089A>G p.G363= (on ENST00000610222 / NM_001366225.1; = p.G278= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV101059654; called by muse, mutect2, varscan2
- TLN2 | c.5079C>T p.D1693= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs370731939, COSV100169356; called by muse, mutect2, varscan2
- TONSL | c.3003C>T p.D1001= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as rs558700548, COSV101340271; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501143 C>T | 5'Flank (SNP) | VAF 21/44 reads (48%) | catalogued as rs539201929; called by muse, mutect2, varscan2
- RAPGEF1 | c.1855-1857_1855-1856del | Intron (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
